Somatic mutation profile of tumor specimen MP2PRT-PAPGLX-TMP1-A (aliquot MP2PRT-PAPGLX-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPGLX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,378 days).
Specimen MP2PRT-PAPGLX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fc040d2-5ffe-40fb-b1a5-be0608be61cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPGLX-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPGLX-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbc015ee-daa1-4886-aa91-c63d1e251ac9

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 86/315 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763680928, COSV55391134; called by muse, varscan2
- EYS | c.5950G>A p.A1984T | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs574948016; called by muse, mutect2, varscan2
- OPLAH | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 85/314 reads (27%) | catalogued as rs373732666; called by muse, mutect2, varscan2
- OPRK1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 96/386 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as rs200159306, COSV55568063; called by muse, mutect2, varscan2
- SERTAD4 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs750746678, COSV100882650; called by muse, mutect2, varscan2
- TGM4 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781223579, COSV56095392; called by muse, mutect2
- THSD7B | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419170612; called by muse, mutect2, varscan2
- ATP6V0C | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 97/430 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- GDA | c.1028T>C p.I343T | Missense Mutation (SNP) | VAF 81/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- IGHV3-64 | chr14:106657722 GTCTCT>AGGA | Missense Mutation (DEL) | VAF 12/89 reads (13%) | called by pindel, varscan2*
- MCC | c.141C>A p.C47* | Nonsense Mutation (SNP) | VAF 112/465 reads (24%) | called by muse, mutect2, varscan2
- NR2F1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, varscan2
- VPS50 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV4-61 | c.356delinsGC p.*119G | Silent (INS) | VAF 36/208 reads (17%) | called by mutect2*, pindel, varscan2*
- RET | c.1182C>T p.N394= | Silent (SNP) | VAF 143/534 reads (27%) | catalogued as rs376465385, CM000032; ClinVar: likely benign; called by muse, mutect2, varscan2
- TLN2 | c.3522C>G p.A1174= | Silent (SNP) | VAF 84/342 reads (25%) | called by muse, mutect2, varscan2
